CCDI case PBCNBB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/c140e1c5-8857-4975-9ba0-585a3fd1aa60

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 3.7 years (1,363 days).

Biospecimens (3 samples)
- Sample 0DVSBO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVSBV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVSC9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
